TCGA case TCGA-76-6283 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5c9b14e-3bc7-4892-bd51-4cd1599819ec

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 165 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,002 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No; Days to last follow up: 165 days.

Follow-up (2 entries)
- Days to follow up: 165 days; Disease response: With Tumor.
- Karnofsky performance status: 0.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-76-6283-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-76-6283-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
  Slide TCGA-76-6283-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
- Sample TCGA-76-6283-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Follow-up form: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 165 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 165 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 165 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-76-6283-01A-11D-1842-01): tumor purity 0.91, ploidy 2.07, whole-genome doublings 0.
